Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5884, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5884-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1. SP: Kidney, right; partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy

Tumor Type:

Renal cell carcinoma - Papillary type
(type II)

Tumor Size:

Greatest diameter is 1.1 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation, labeled "right renal tumor stitch marks deep surgical margin", and consists of a wedge shaped portion of kidney with a suture marking the deep margin, measuring 2.5 x 1.7 x 1.2 cm. The margin is inked black and the specimen is serially sectioned to reveal a sub-capsular yellow nodule measuring 1.1 x 1.0 x 0.5 cm. The clearance from the resection margin is 0.5 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. Part is submitted for frozen section.

Summary of sections:

FSC -- frozen section control

T --entire tumor to margin

U-- uninvolved kidney

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
2	t	2
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Right renal tumor [REDACTED] Renal cortical neoplasm. Margin is free of tumor.

PERMANENT DIAGNOSIS: SAME

[REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file 3d0e3be8-b958-4d20-bcf3-437d3d580cb1 (TCGA-BQ-5884.ED5C224B-AD4A-409D-941C-0EFE21CC3729.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).